Gene-level copy-number profile of tumor specimen HTMCP-03-06-02377-01A from CGCI case HTMCP-03-06-02377, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 48.7 years (17,788 days).
Specimen HTMCP-03-06-02377-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2b0d46c4-5a4e-4218-91b5-e5336456d3f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02377-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/6cf8bd09-5d86-4063-9275-a6a00a13d598

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 136; copy number 1: 3,897; copy number 2: 51,538; copy number 3: 2,302; copy number 4: 335; copy number 5: 61; copy number 6: 38; copy number 7: 47; copy number 11: 5; copy number 12: 3; copy number 15: 5; copy number 33: 2; copy number 38: 8; copy number 66: 1; copy number 71: 4; copy number 97: 17.

Homozygous deletions (total copy number 0; autosomes only): 136 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr9:21,160,235–31,645,160, 121 genes (broad region; genes not listed).
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 191 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,330,935, 14 genes, copy number 6 (within-gene range 4–6): TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr9:32,293,558–32,727,522, 13 genes, copy number 11–15: RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1.
- chr11:99,020,949–102,498,801, 33 genes, copy number 6–97: CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2.
- chr14:22,185,562–22,497,718, 46 genes, copy number 7: TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr17:61,361,668–61,485,110, 7 genes, copy number 5 (within-gene range 2–5): AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1.
- chr20:30,214,765–31,645,006, 39 genes, copy number 5: CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2.
- chr22:33,162,226–33,922,841, 1 gene, copy number 5 (within-gene range 2–5): LARGE1.
- chr22:33,436,582–36,028,824, 37 genes, copy number 5–6: MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1.

Autosomal genes at a single copy (total copy number 1): 3,838. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
